Gene-level copy-number profile of tumor specimen ALCH-B2BY-TTP1-A from ALCHEMIST case ALCH-B2BY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.2 years (20,176 days).
Specimen ALCH-B2BY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 25af1be4-d33b-4857-a31f-fc5e51480782.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2BY-NB3-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,738 have no estimate.
https://portal.gdc.cancer.gov/files/86024149-fced-41b8-96ac-26d433f9193a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 14,988; copy number 2: 37,895; copy number 3: 2,749; copy number 4: 3,187; copy number 5: 1; copy number 6: 4; copy number 10: 3; copy number 15: 2.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,625,015–3,652,761, 2 genes (within-gene range 0–2): TPRG1L, WRAP73.
- chr1:53,344,031–53,365,473, 2 genes: AC119428.2, AC119428.1.
- chr1:103,523,562–103,668,268, 7 genes (within-gene range 0–1): RN7SKP285, RNPC3, AMY2B, ACTG1P4, AMY2A, AMY1A, AC105272.1.
- chr3:129,591,349–129,591,635, 1 gene (within-gene range 0–2): RN7SL752P.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes (within-gene range 0–1): AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr9:41,974,362–42,011,610, 3 genes (within-gene range 0–1): RBM17P3, CR788268.1, RN7SL343P.
- chr15:25,159,221–25,185,712, 11 genes (within-gene range 0–1): SNORD115, DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9.
- chr17:82,381,110–82,382,690, 1 gene: AC132938.1.
- chr17:82,400,703–82,401,382, 1 gene (within-gene range 0–2): AC132938.2.
- chr21:43,446,601–43,453,902, 1 gene: LINC00319.
- chr22:20,241,415–20,313,216, 3 genes: RTN4R, MIR1286, AC007663.1.
- chr22:46,576,012–46,679,790, 1 gene: GRAMD4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:70,449,636–70,500,903, 3 genes, copy number 10: AC146944.2, NAIPP1, AC146944.1.
- chr5:70,968,166–71,025,339, 1 gene, copy number 5: NAIP.
- chr16:629,239–649,200, 4 genes, copy number 6 (within-gene range 1–6): WFIKKN1, METTL26, MCRIP2, AL022341.1.
- chr21:43,461,960–43,479,534, 2 genes, copy number 15: LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 12,441. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
